CPTAC case C3L-01277 — Uterus, NOS — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Uterus, NOS. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/3df584e9-19e8-43ab-abfb-edb4e55af264

Demographics
Sex at birth: female; Race: white; Year of birth: 1955; Vital status: Alive.

Diagnoses (1)
1. Endometrioid adenocarcinoma, NOS: ICD-O-3 morphology code: 8380/3; Tissue or organ of origin: Uterus, NOS; Site of resection or biopsy: Corpus uteri; Age at diagnosis: 61.2 years (22,367 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N1; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; FIGO stage: Stage IV; Tumor grade: G3; Residual disease: RX; Last known disease status: With tumor; Days to last known disease status: 1,732 days (4.7 years); Progression or recurrence: yes; Days to last follow up: 1,732 days (4.7 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 3.1 cm; Lymph node involvement: Positive; Lymph nodes positive: 3; Lymph nodes tested: 20; Margin status: Uninvolved.
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (5 entries)
- Days to follow up: 380 days (1.0 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 742 days (2.0 years); Disease response: Tumor Free; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 996 days (2.7 years); Disease response: With Tumor; Karnofsky performance status: 20; ECOG performance status: 3.
- Days to follow up: 996 days (2.7 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 986 days (2.7 years); Karnofsky performance status: 20; ECOG performance status: 3.
- Days to follow up: 1,732 days (4.7 years); Disease response: With Tumor; Karnofsky performance status: 20; ECOG performance status: 3.

Other clinical attributes
- Weight: 89.81 kg; Height: 152.4 cm; BMI: 38.66.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (6 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01277-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 29 days; Initial weight: 220 mg; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01277-21: Section location: The mass occupies the anterior and posterior aspects of the endometrial cavity; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3L-01277-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 29 days; Initial weight: 90 mg; Time between excision and freezing: 17 minutes; Method of sample procurement: Surgical Resection; Diagnosis pathologically confirmed: Yes.
- Sample C3L-01277-11: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Uterus; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 29 days; Time between excision and freezing: 15 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
- Samples C3L-01277-31, C3L-01277-32 (2 with the same recorded description): Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Sample C3L-01277-72: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Buffy Coat; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 29 days; Method of sample procurement: Blood Draw.
